Somatic mutation profile of tumor specimen TCGA-XU-AAXZ-01A (aliquot TCGA-XU-AAXZ-01A-11D-A428-09) from TCGA case TCGA-XU-AAXZ, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 63.9 years (23,324 days).
Specimen TCGA-XU-AAXZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6c7645e-5de1-4fba-b4dc-081b45237e91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAXZ-10A (Blood Derived Normal), aliquot TCGA-XU-AAXZ-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d835109-5657-4582-bc9d-095da21b1ffc

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPT | c.2272G>A p.G758R (on ENST00000262410 / NM_001377265.1; = p.G366R on NM_005910.5) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948573449, CM121237, COSV52240278; called by muse, mutect2
- ACACB | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- DEUP1 | c.328_329insG p.L110Rfs*20 | Frame Shift Ins (INS) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- ITGA10 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, varscan2
- MAP3K1 | c.3745A>G p.I1249V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SMAP2 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LILRA2 | c.1344G>A p.E448= (on ENST00000391738 / NM_001130917.3; = p.E431= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs973961385; called by muse, mutect2
- N4BP2 | c.3678G>T p.V1226= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- RAI14 | c.654A>G p.G218= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- MBD2 | c.702+2011A>G | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as rs1263087972; called by muse, mutect2, varscan2
